Somatic mutation profile of tumor specimen MP2PRT-PAVPER-TMP1-A (aliquot MP2PRT-PAVPER-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVPER, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (933 days).
Specimen MP2PRT-PAVPER-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 974bc170-6ffb-4009-80bd-b0340eef026b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPER-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPER-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccc356e7-c878-42c0-815d-b17ce5a1e611

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, In Frame Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 50/296 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD18A | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1563966592; called by muse, mutect2, varscan2
- GRID1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 103/415 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.098); catalogued as rs371302230; called by muse, mutect2, varscan2
- HECW1 | c.4462G>A p.A1488T | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs758768640, COSV67831804; called by muse, mutect2, varscan2
- KRT26 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372502675, COSV56970677, COSV56973714; called by muse, mutect2, varscan2
- PDE6A | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768596256, COSV54926143; ClinVar: uncertain significance; called by muse, mutect2
- PDILT | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs757403657, COSV56700606, COSV56705724; called by muse, mutect2, varscan2
- ARID5B | c.444_445insACG p.Q148_S149insT | In Frame Ins (INS) | VAF 40/468 reads (9%) | called by mutect2, pindel
- IGKV2-30 | chr2:89244770 ACCACTGTGGGAGGCCAGTGTG>CGCTT | Missense Mutation (DEL) | VAF 15/156 reads (10%) | called by mutect2*, pindel, varscan2*
- TRAJ29 | c.1_2delinsTTGTTTTT p.*1_N2insVF | In Frame Ins (INS) | VAF 46/229 reads (20%) | called by pindel, varscan2*
- OCRL | c.2244C>T p.Y748= | Silent (SNP) | VAF 60/388 reads (15%) | catalogued as rs781297236, CM055472; called by muse, mutect2, varscan2
- PTCH1 | c.1998G>A p.T666= | Silent (SNP) | VAF 164/498 reads (33%) | catalogued as rs369710438, COSV59473269; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
